Somatic mutation profile of tumor specimen TCGA-06-0744-01A (aliquot TCGA-06-0744-01A-01D-1492-08) from TCGA case TCGA-06-0744, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.0 years (24,471 days).
Specimen TCGA-06-0744-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e954b455-865e-4fb8-9541-1febef61ccd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0744-10A (Blood Derived Normal), aliquot TCGA-06-0744-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26a5a0b2-cf81-404b-a266-3fcff784336e

The open-access MAF lists 75 somatic variants for this specimen: 56 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 51, Silent 19, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 47/97 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC097636.1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs781398221, COSV71309506; called by muse, mutect2, varscan2
- AC134980.2 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 51/60 reads (85%) | SIFT tolerated (0.53); PolyPhen benign (0.075); catalogued as rs375688421, COSV60906944; called by muse, mutect2, varscan2
- ADAM29 | c.519C>A p.C173* | Nonsense Mutation (SNP) | VAF 46/109 reads (42%) | catalogued as COSV63663937; called by muse, mutect2, varscan2
- ADAMTS12 | c.3139G>A p.A1047T | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV61263771; called by muse, mutect2, varscan2
- ADGRF4 | c.738C>A p.H246Q | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as COSV51952711; called by muse, mutect2, varscan2
- AHNAK2 | c.12742C>T p.P4248S | Missense Mutation (SNP) | VAF 145/340 reads (43%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.472); catalogued as COSV60916443; called by muse, mutect2, varscan2
- ARHGEF35 | c.1283T>A p.L428H | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.253); catalogued as COSV65312723; called by muse, mutect2, varscan2
- ARID4B | c.2739T>A p.D913E | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.031); catalogued as COSV51603840; called by muse, mutect2, varscan2
- ATR | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV63386876; called by muse, mutect2, varscan2
- C2CD2L | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs750634362, COSV60884096; called by muse, mutect2, varscan2
- CCDC8 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.156); catalogued as COSV56773500; called by muse, mutect2, varscan2
- CENPE | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV54381733; called by muse, mutect2, varscan2
- CHRNA4 | c.1874G>A p.G625D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV64719597; called by muse, mutect2
- DGKD | c.2916G>A p.M972I (on ENST00000264057 / NM_152879.3; = p.M928I on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV51046687, COSV51049750; called by muse, mutect2, varscan2
- DOCK10 | c.2603A>G p.Q868R | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51406345; called by muse, mutect2, varscan2
- DOCK5 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52402689; called by muse, mutect2, varscan2
- DOP1A | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52710715; called by muse, mutect2, varscan2
- ELMO1 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs772235613, COSV60305715; called by muse, mutect2, varscan2
- EXOSC9 | c.1040G>C p.W347S | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54666143; called by muse, mutect2, varscan2
- GYPA | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs572116498, COSV51626818; called by muse, mutect2, varscan2
- IGHE | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs781819607; called by muse, mutect2, varscan2
- JAKMIP1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51533358; called by mutect2, varscan2
- KNG1 | c.1039-1G>A p.X347_splice | Splice Site (SNP) | VAF 25/60 reads (42%) | catalogued as COSV53978207; called by muse, mutect2, varscan2
- LRFN5 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as rs772023044, COSV53257915; called by muse, mutect2, varscan2
- NMUR2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 73/99 reads (74%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs759161756, COSV54919615; called by muse, mutect2, varscan2
- NSUN5 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs781934018, COSV53091830; called by muse, mutect2, varscan2
- OR4A47 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV71444881; called by muse, mutect2, varscan2
- OR5I1 | c.21C>G p.N7K | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV56887143; called by muse, mutect2
- OSMR | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV57085713; called by muse, mutect2, varscan2
- PCDHA8 | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 65/118 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as rs1554139855, COSV65327415; called by muse, mutect2, varscan2
- PCDHB7 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs782388523, COSV50763014; called by muse, mutect2, varscan2
- PON1 | c.892A>T p.N298Y | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.144); catalogued as COSV55932100; called by muse, mutect2, varscan2
- PRSS48 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778098061, COSV71613876; called by mutect2, varscan2
- PSMB11 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV68430212; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs371085767; called by muse, mutect2, varscan2
- RADX | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV65318749; called by muse, mutect2, varscan2
- RIC8A | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV100254741, COSV57315375; called by muse, mutect2, varscan2
- RIMS2 | c.2944C>T p.R982* (on ENST00000666250 / NM_001348490.2; = p.R790* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 62/142 reads (44%) | catalogued as rs201715496, COSV51684946; called by muse, mutect2, varscan2
- SAMD9 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV66075578; called by muse, mutect2, varscan2
- SERPINB4 | c.470-1G>A p.X157_splice | Splice Site (SNP) | VAF 42/105 reads (40%) | catalogued as COSV61985045; called by muse, mutect2, varscan2
- SLC22A8 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs936852997, COSV60325143; called by muse, mutect2, varscan2
- SPEG | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV56669839; called by muse, mutect2, varscan2
- SYNM | c.3478C>A p.Q1160K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV50442192; called by muse, mutect2, varscan2
- TAF1L | c.5018C>G p.T1673R | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.079); catalogued as COSV54263085, COSV54271887; called by muse, mutect2
- TRABD2A | c.1258C>T p.R420W (on ENST00000409520 / NM_001277053.2; = p.R371W on NM_001080824.3) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs1401600406, COSV52860910; called by muse, mutect2, varscan2
- TRIM10 | c.440A>G p.H147R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as rs759629347, COSV64989617; called by muse, mutect2, varscan2
- TRMO | c.889G>T p.V297F | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV64291905; called by muse, mutect2, varscan2
- TSPAN9 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.139); catalogued as rs1022296216, COSV50723984; called by muse, mutect2, varscan2
- TTN | c.88507C>T p.R29503W (on ENST00000591111; = p.R22079W on NM_003319.4) | Missense Mutation (SNP) | VAF 114/252 reads (45%) | PolyPhen probably damaging (0.999); catalogued as rs770088691, COSV60111692; called by muse, mutect2, varscan2
- UROC1 | c.1014C>G p.D338E | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV52033636; called by muse, mutect2, varscan2
- ZNF493 | c.1097G>A p.C366Y | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV62750190; called by muse, mutect2, varscan2
- ZNF638 | c.4396G>A p.G1466R | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52487973; called by muse, mutect2, varscan2
- HDHD2 | c.723_726del p.Y241* | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | called by pindel, varscan2
- IGHV3-72 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- OCA2 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2
- A1BG | c.570C>T p.G190= | Silent (SNP) | VAF 75/232 reads (32%) | catalogued as rs138577019; called by muse, mutect2, varscan2
- ADAMTS12 | c.762C>T p.A254= | Silent (SNP) | VAF 59/142 reads (42%) | catalogued as rs775100937, COSV61263775; called by muse, mutect2, varscan2
- ANKS6 | c.2058G>A p.R686= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV62050411; called by muse, mutect2, varscan2
- C2orf78 | c.1623C>T p.S541= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs373917345; called by muse, mutect2, varscan2
- CCDC110 | c.498C>T p.S166= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as rs761432896, COSV56871458; called by muse, mutect2, varscan2
- CMYA5 | c.10443G>A p.L3481= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV101483967, COSV71406175; called by muse, mutect2, varscan2
- CPQ | c.426T>A p.P142= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV55146773; called by muse, mutect2, varscan2
- GALNT18 | c.924C>T p.Y308= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV57149845; called by muse, mutect2, varscan2
- GRIN3A | c.627C>T p.L209= | Silent (SNP) | VAF 36/48 reads (75%) | catalogued as COSV62454249; called by muse, mutect2, varscan2
- HTR3A | c.1332C>T p.R444= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as rs766338857, COSV55469643; called by muse, mutect2, varscan2
- LAMA1 | c.1620G>A p.P540= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as rs765638301, COSV67535741; called by muse, mutect2, varscan2
- MAGEB6B | c.774C>T p.S258= | Silent (SNP) | VAF 64/71 reads (90%) | catalogued as rs751739511; called by muse, mutect2, varscan2
- MUC17 | c.1251T>C p.P417= | Silent (SNP) | VAF 137/490 reads (28%) | catalogued as COSV60289751; called by muse, mutect2, varscan2
- OR10G9 | c.795C>T p.D265= | Silent (SNP) | VAF 102/256 reads (40%) | catalogued as rs758211969, COSV66685718, COSV66685952; called by muse, mutect2, varscan2
- OR6M1 | c.651C>T p.Y217= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs1417385102, COSV58433711; called by muse, mutect2, varscan2
- POU1F1 | c.54C>T p.D18= | Silent (SNP) | VAF 43/78 reads (55%) | catalogued as rs1478435601, COSV60156018; called by muse, mutect2, varscan2
- RFPL2 | c.270C>T p.D90= | Silent (SNP) | VAF 50/65 reads (77%) | catalogued as COSV50711538; called by muse, mutect2, varscan2
- SIGLEC15 | c.738C>T p.S246= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV67181172; called by muse, varscan2
- TRIM40 | c.567G>A p.A189= (on ENST00000376724; = p.A160= on NM_138700.4) | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs759209501, COSV57156763; called by muse, mutect2, varscan2
